Somatic mutation profile of tumor specimen TCGA-96-8169-01A (aliquot TCGA-96-8169-01A-11D-2293-08) from TCGA case TCGA-96-8169, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 67.6 years (24,674 days).
Specimen TCGA-96-8169-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 350aabe2-0053-4185-bd0d-af8bd6196fd2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-96-8169-10A (Blood Derived Normal), aliquot TCGA-96-8169-10A-01D-2293-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f6a0c204-7a83-4638-a62c-f44c5dada502

The open-access MAF lists 181 somatic variants for this specimen: 127 protein-altering or splice-affecting, 47 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 105, Silent 47, Nonsense Mutation 11, Splice Site 6, Intron 4, Frame Shift Del 4, RNA 2, 5'Flank 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL11A2 | c.3058C>T p.R1020* (on ENST00000341947 / NM_080680.3; = p.R913* on NM_080679.2) | Nonsense Mutation (SNP) | VAF 4/42 reads (10%) | catalogued as rs911722283, COSV100553453; ClinVar: likely pathogenic; called by muse, mutect2
- MVK | c.928G>A p.V310M | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs104895319, CM115597, CM990889, COSV57332161, COSV99950108; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.949C>T p.Q317* | Nonsense Mutation (SNP) | VAF 95/158 reads (60%) | hotspot (GDC flag); catalogued as rs764735889, COSV52685086, COSV53209009; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.6961G>A p.G2321R (on ENST00000272895 / NM_173076.3; = p.G2003R on NM_015657.3) | Missense Mutation (SNP) | VAF 25/133 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs760439616, COSV99792705; called by muse, mutect2, varscan2
- ABCC5 | c.3360G>T p.M1120I | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV99657922; called by muse, mutect2, varscan2
- ACTA1 | c.971C>A p.P324H | Missense Mutation (SNP) | VAF 50/142 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as rs1489027332, COSV100796816; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.598G>A p.A200T | Missense Mutation (SNP) | VAF 27/206 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100417094; called by muse, mutect2, varscan2
- ADGRA1 | c.39A>T p.R13S | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as COSV101658626; called by mutect2, varscan2
- ADGRL3 | c.2716C>G p.R906G (on ENST00000506720 / NM_001322402.2; = p.R838G on NM_015236.6) | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV101547330, COSV72229448; called by muse, mutect2, varscan2
- AGFG1 | c.1630-1G>T p.X544_splice | Splice Site (SNP) | VAF 18/107 reads (17%) | catalogued as COSV100029254; called by muse, mutect2, varscan2
- AKAP9 | c.3092C>T p.A1031V | Missense Mutation (SNP) | VAF 6/112 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.026); catalogued as COSV100663404; called by muse, mutect2
- APBA1 | c.2008G>T p.V670L | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.553); catalogued as COSV99597458; called by muse, mutect2, varscan2
- APOB | c.12577C>G p.L4193V | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV99268794; called by muse, mutect2, varscan2
- APOL1 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 33/132 reads (25%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as rs1334345255, COSV100046306; called by muse, mutect2, varscan2
- ATRNL1 | c.2230C>A p.P744T | Missense Mutation (SNP) | VAF 32/125 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100747188; called by muse, mutect2, varscan2
- CACNA1G | c.3491T>C p.L1164P | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.515); catalogued as COSV100662815; called by muse, mutect2, varscan2
- CCDC40 | c.1622T>C p.I541T | Missense Mutation (SNP) | VAF 38/105 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100884360; called by muse, mutect2, varscan2
- CCDC9B | c.445G>A p.A149T | Missense Mutation (SNP) | VAF 29/133 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.23); catalogued as COSV101233560; called by muse, mutect2, varscan2
- CCNB3 | c.3517-2A>T p.X1173_splice | Splice Site (SNP) | VAF 45/196 reads (23%) | catalogued as COSV99330115; called by muse, mutect2, varscan2
- CDH10 | c.781G>T p.D261Y | Missense Mutation (SNP) | VAF 21/133 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100053608, COSV52572125; called by muse, mutect2, varscan2
- CDH9 | c.325G>T p.D109Y | Missense Mutation (SNP) | VAF 97/273 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99142545, COSV99163558; called by muse, mutect2, varscan2
- CFAP70 | c.73A>G p.K25E | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1454091351, COSV100161197; called by muse, mutect2, varscan2
- CMSS1 | c.589C>T p.Q197* | Nonsense Mutation (SNP) | VAF 11/82 reads (13%) | catalogued as COSV101375680; called by muse, mutect2, varscan2
- CNTN5 | c.2339T>C p.V780A | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.376); catalogued as COSV99682760; called by muse, mutect2, varscan2
- DCC | c.2288G>A p.G763D | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100503900, COSV59123438; called by muse, mutect2, varscan2
- DNHD1 | c.13343G>A p.R4448Q | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.045); catalogued as rs747701056, COSV99601219; called by muse, mutect2, varscan2
- DPH7 | c.883C>T p.H295Y | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs924972997, COSV99483790; called by muse, mutect2, varscan2
- E2F5 | c.539A>T p.N180I | Missense Mutation (SNP) | VAF 32/131 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.028); catalogued as COSV99809848; called by muse, mutect2, varscan2
- ERCC6 | c.1439T>C p.L480P | Missense Mutation (SNP) | VAF 17/124 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.36); catalogued as COSV100876366; called by muse, mutect2, varscan2
- FAM184A | c.1693G>T p.G565C | Missense Mutation (SNP) | VAF 30/184 reads (16%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.979); catalogued as COSV100138486; called by muse, mutect2, varscan2
- FAM47A | c.1128C>A p.H376Q | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.027); catalogued as COSV60495201, COSV60499058; called by muse, mutect2, varscan2
- FBXO41 | c.1656G>C p.K552N | Missense Mutation (SNP) | VAF 47/198 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99721744; called by muse, mutect2, varscan2
- FREM2 | c.2215C>T p.R739C | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.761); catalogued as rs771621330, COSV54834049; called by muse, mutect2, varscan2
- GALNT8 | c.980T>A p.F327Y | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.18); PolyPhen probably damaging (1); catalogued as COSV99363362; called by muse, mutect2, varscan2
- GATA3 | c.668C>T p.P223L | Missense Mutation (SNP) | VAF 31/126 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.466); catalogued as rs1400015722, COSV60517174; called by muse, mutect2, varscan2
- GLB1L2 | c.382G>T p.G128W | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100335557; called by muse, mutect2, varscan2
- GNG11 | c.158T>C p.L53P | Missense Mutation (SNP) | VAF 25/141 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99949450; called by muse, mutect2, varscan2
- GNL1 | c.181C>T p.R61C | Missense Mutation (SNP) | VAF 28/164 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as COSV100925455; called by muse, mutect2, varscan2
- GOLIM4 | c.458A>G p.H153R | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs138686297; called by muse, mutect2, varscan2
- GON4L | c.4374A>T p.E1458D | Missense Mutation (SNP) | VAF 11/222 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.254); catalogued as COSV99676238; called by muse, mutect2
- GRIN3A | c.1612C>A p.P538T | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100701968; called by muse, mutect2, varscan2
- GSK3B | c.784G>A p.G262S | Missense Mutation (SNP) | VAF 125/732 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV99955910; called by muse, mutect2, varscan2
- GTF2H1 | c.580G>C p.E194Q | Missense Mutation (SNP) | VAF 18/125 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.029); catalogued as COSV99786713; called by muse, mutect2, varscan2
- H2AC15 | c.140G>T p.G47V | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV57585312; called by muse, mutect2, varscan2
- H2BC8 | c.263C>G p.S88W | Missense Mutation (SNP) | VAF 20/167 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.332); catalogued as COSV99773464; called by muse, mutect2, varscan2
- HTATSF1 | c.402T>A p.N134K | Missense Mutation (SNP) | VAF 64/222 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.982); catalogued as COSV99511989; called by muse, mutect2, varscan2
- HYOU1 | c.550G>T p.E184* | Nonsense Mutation (SNP) | VAF 11/91 reads (12%) | catalogued as COSV101345545, COSV101345709; called by muse, mutect2, varscan2
- IL1RAPL2 | c.1861T>A p.Y621N | Missense Mutation (SNP) | VAF 9/170 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV100782257; called by muse, mutect2
- IL1RL1 | c.1360C>A p.H454N | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT tolerated (0.6); PolyPhen benign (0.145); catalogued as COSV99294680; called by muse, mutect2, varscan2
- IL23R | c.526T>A p.S176T | Missense Mutation (SNP) | VAF 24/129 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.25); catalogued as COSV100724990; called by muse, mutect2, varscan2
- IQCJ-SCHIP1 | c.457T>A p.Y153N (on ENST00000485419 / NM_001197113.1; = p.Y77N on NM_014575.3) | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV100542618; called by muse, mutect2, varscan2
- IRF4 | c.534G>A p.W178* | Nonsense Mutation (SNP) | VAF 51/286 reads (18%) | catalogued as COSV101110989; called by muse, mutect2, varscan2
- JAG2 | c.1097C>T p.P366L | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs140813175; called by muse, mutect2
- KCNA10 | c.979A>C p.T327P | Missense Mutation (SNP) | VAF 12/205 reads (6%) | SIFT tolerated (0.43); PolyPhen benign (0.005); catalogued as COSV100871513; called by muse, mutect2
- KRT74 | c.268G>T p.A90S | Missense Mutation (SNP) | VAF 6/105 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.271); catalogued as COSV99977740; called by muse, mutect2
- KRTAP3-3 | c.80G>T p.R27L | Missense Mutation (SNP) | VAF 63/168 reads (38%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.995); catalogued as rs762319985, COSV101195963, COSV101195983; called by muse, mutect2, varscan2
- KRTAP6-3 | c.236G>T p.G79V | Missense Mutation (SNP) | VAF 6/37 reads (16%) | PolyPhen probably damaging (0.974); catalogued as COSV101196528; called by muse, mutect2, varscan2
- LCE3D | c.252C>A p.C84* | Nonsense Mutation (SNP) | VAF 79/215 reads (37%) | catalogued as rs374860616, COSV100909893, COSV64231030; called by muse, mutect2, varscan2
- LCT | c.2014C>T p.Q672* | Nonsense Mutation (SNP) | VAF 31/104 reads (30%) | catalogued as COSV99930721; called by muse, mutect2, varscan2
- LMLN | c.1057C>T p.R353* | Nonsense Mutation (SNP) | VAF 28/128 reads (22%) | catalogued as rs753033262, COSV100218988; called by muse, mutect2, varscan2
- LRP1 | c.4922G>A p.R1641Q | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99677914; called by muse, mutect2, varscan2
- LRRIQ1 | c.266C>G p.S89C | Missense Mutation (SNP) | VAF 19/133 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV101277756; called by muse, mutect2
- LRRK2 | c.6613G>C p.V2205L | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.174); catalogued as rs767045562, COSV100111520; called by muse, mutect2, varscan2
- LRRTM3 | c.1556T>C p.V519A | Missense Mutation (SNP) | VAF 37/199 reads (19%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as rs1304476461, COSV100791981; called by muse, mutect2, varscan2
- MBD6 | c.2720C>G p.P907R | Missense Mutation (SNP) | VAF 18/129 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100851884; called by muse, mutect2, varscan2
- MEX3B | c.1120C>T p.P374S | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as COSV100314276; called by muse, mutect2, varscan2
- MNDA | c.1021A>G p.I341V | Missense Mutation (SNP) | VAF 31/157 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.595); catalogued as COSV100933483; called by muse, mutect2, varscan2
- MPP7 | c.953-2A>T p.X318_splice | Splice Site (SNP) | VAF 13/45 reads (29%) | catalogued as COSV100518087, COSV61737167; called by muse, varscan2
- MYCT1 | c.380G>T p.R127L | Missense Mutation (SNP) | VAF 24/158 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100924104, COSV65890996; called by muse, mutect2, varscan2
- NEB | c.20A>G p.Y7C | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV99429337; called by muse, mutect2, varscan2
- NELL1 | c.1058G>T p.C353F | Missense Mutation (SNP) | VAF 38/194 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.802); catalogued as rs551356049, COSV54273501; called by muse, mutect2, varscan2
- NELL1 | c.2161G>A p.G721R | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779365727, COSV54324061; called by muse, mutect2, varscan2
- NLRP14 | c.1061G>T p.S354I | Missense Mutation (SNP) | VAF 38/133 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV100204525, COSV100205545, COSV55065150; called by muse, mutect2, varscan2
- NOTCH1 | c.3206A>G p.K1069R | Missense Mutation (SNP) | VAF 56/233 reads (24%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as COSV53071535; called by muse, mutect2, varscan2
- NPBWR2 | c.262G>T p.A88S | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV63900279; called by muse, mutect2, varscan2
- NPR2 | c.1400T>G p.F467C | Missense Mutation (SNP) | VAF 27/188 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV100709815; called by muse, mutect2, varscan2
- OR2L13 | c.617T>G p.L206R | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100813924, COSV63554950; called by muse, mutect2, varscan2
- PCDHGA5 | c.1576A>G p.R526G | Missense Mutation (SNP) | VAF 41/346 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.114); catalogued as COSV99549926; called by muse, mutect2, varscan2
- PDE4B | c.1045G>T p.G349C | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100305699; called by muse, mutect2, varscan2
- PEG3 | c.3194G>T p.G1065V | Missense Mutation (SNP) | VAF 30/169 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV99690979; called by muse, mutect2, varscan2
- PHLDB1 | c.718G>A p.G240S | Missense Mutation (SNP) | VAF 115/266 reads (43%) | SIFT tolerated (0.21); PolyPhen benign (0.112); catalogued as rs781979180, COSV100616585, COSV100616885; called by muse, mutect2, varscan2
- PLCB4 | c.1234T>C p.C412R | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99597332; called by muse, mutect2, varscan2
- POLR3B | c.1772G>A p.R591K | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99944007; called by muse, mutect2, varscan2
- PRAMEF12 | c.1065A>T p.L355F | Missense Mutation (SNP) | VAF 35/158 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100743675, COSV63214831; called by muse, mutect2, varscan2
- PRPF39 | c.82C>G p.P28A | Missense Mutation (SNP) | VAF 33/178 reads (19%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0.003); catalogued as COSV100866067; called by muse, mutect2, varscan2
- PRSS58 | c.534G>T p.M178I | Missense Mutation (SNP) | VAF 32/251 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.268); catalogued as COSV101616182; called by muse, mutect2, varscan2
- PTPRZ1 | c.5998G>A p.V2000M | Missense Mutation (SNP) | VAF 35/137 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101100984, COSV99069460; called by muse, mutect2, varscan2
- RASA1 | c.693-1G>A p.X231_splice | Splice Site (SNP) | VAF 6/58 reads (10%) | catalogued as COSV99169568, COSV99171547; called by muse, mutect2, varscan2
- RBM23 | c.4G>T p.A2S | Missense Mutation (SNP) | VAF 53/197 reads (27%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.007); catalogued as COSV100321588; called by muse, mutect2, varscan2
- RGS7BP | c.524C>A p.T175K | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); catalogued as COSV61834906; called by muse, mutect2, varscan2
- RGS9 | c.1725G>C p.K575N | Missense Mutation (SNP) | VAF 65/174 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.198); catalogued as COSV99288262; called by muse, mutect2, varscan2
- RYR2 | c.3298C>G p.R1100G | Missense Mutation (SNP) | VAF 77/241 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.258); catalogued as COSV100773446, COSV63707775; called by muse, mutect2, varscan2
- SFMBT1 | c.2026G>A p.V676I | Missense Mutation (SNP) | VAF 17/122 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.296); catalogued as COSV99966540; called by muse, mutect2, varscan2
- SHROOM3 | c.4709+1G>C p.X1570_splice | Splice Site (SNP) | VAF 7/32 reads (22%) | catalogued as COSV99935721; called by muse, mutect2, varscan2
- SIGLEC5 | c.386G>T p.S129I | Missense Mutation (SNP) | VAF 15/118 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.092); catalogued as COSV99708053; called by muse, mutect2, varscan2
- SLC15A2 | c.1003-2A>G p.X335_splice | Splice Site (SNP) | VAF 35/295 reads (12%) | catalogued as COSV99815980; called by muse, mutect2, varscan2
- SMG9 | c.832A>G p.I278V | Missense Mutation (SNP) | VAF 18/116 reads (16%) | SIFT tolerated (0.72); PolyPhen benign (0.02); catalogued as rs572976215, COSV99526993; called by muse, mutect2, varscan2
- SPEF2 | c.3498G>C p.K1166N | Missense Mutation (SNP) | VAF 67/321 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.963); catalogued as COSV100609315; called by muse, mutect2, varscan2
- SRBD1 | c.2309A>G p.Q770R | Missense Mutation (SNP) | VAF 37/222 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.889); catalogued as COSV99765722; called by muse, mutect2, varscan2
- SSH3 | c.785C>G p.P262R | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as rs750413460, COSV100354961; called by muse, mutect2, varscan2
- STX17 | c.366T>G p.D122E | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV99408231; called by muse, mutect2, varscan2
- STYXL2 | c.2423C>A p.P808H | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.087); catalogued as COSV99610098; called by muse, mutect2, varscan2
- SYNGAP1 | c.3062A>T p.Q1021L | Missense Mutation (SNP) | VAF 106/460 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99539273; called by muse, varscan2
- TAS1R2 | c.2352C>A p.S784R | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.023); catalogued as COSV100946433; called by muse, mutect2, varscan2
- TNN | c.178G>T p.A60S | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.387); catalogued as COSV99511186, COSV99513446; called by muse, mutect2, varscan2
- TRGV2 | c.328G>T p.V110F | Missense Mutation (SNP) | VAF 8/91 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.421); catalogued as rs147335708; called by muse, mutect2
- TRGV2 | c.187C>G p.Q63E | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.212); catalogued as rs1376149624; called by muse, mutect2, varscan2
- TRIM51 | c.830G>T p.G277V | Missense Mutation (SNP) | VAF 8/97 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.114); catalogued as COSV99792404, COSV99793312; called by muse, mutect2
- TRIM60 | c.186C>A p.Y62* | Nonsense Mutation (SNP) | VAF 16/128 reads (13%) | catalogued as COSV61970679; called by muse, mutect2, varscan2
- TRIM60 | c.187A>G p.K63E | Missense Mutation (SNP) | VAF 16/128 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as rs1178416540, COSV100594184; called by muse, mutect2, varscan2
- TTN | c.17213G>T p.G5738V (on ENST00000591111; = p.G4811V on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/52 reads (13%) | PolyPhen benign (0.424); catalogued as COSV100616024; called by muse, mutect2, varscan2
- USP28 | c.601G>T p.E201* | Nonsense Mutation (SNP) | VAF 25/90 reads (28%) | catalogued as COSV50182771; called by muse, mutect2, varscan2
- USP33 | c.528A>C p.E176D | Missense Mutation (SNP) | VAF 37/137 reads (27%) | SIFT tolerated (0.69); PolyPhen benign (0.05); catalogued as COSV100657294; called by muse, mutect2, varscan2
- UTRN | c.442C>T p.Q148* | Nonsense Mutation (SNP) | VAF 16/135 reads (12%) | catalogued as COSV100840792; called by muse, mutect2, varscan2
- VPS35L | c.212G>C p.S71T | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.979); catalogued as COSV99222001; called by muse, mutect2, varscan2
- ZCWPW1 | c.929T>A p.V310E | Missense Mutation (SNP) | VAF 29/170 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100228488; called by muse, mutect2, varscan2
- ZFHX3 | c.8153C>A p.A2718E | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51715193; called by muse, mutect2, varscan2
- ZNF208 | c.2572G>C p.E858Q | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV101237164, COSV101237208, COSV101237273; called by muse, mutect2, varscan2
- ZNF333 | c.1405G>A p.V469M | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.4); PolyPhen benign (0.015); catalogued as rs180895105, COSV99469689; called by muse, mutect2, varscan2
- ZNF460 | c.932G>T p.S311I | Missense Mutation (SNP) | VAF 32/119 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.152); catalogued as COSV100828151; called by muse, mutect2, varscan2
- ZNF480 | c.791G>T p.C264F | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100574363; called by muse, mutect2, varscan2
- ZNF644 | c.1733G>T p.G578V | Missense Mutation (SNP) | VAF 35/201 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.058); catalogued as COSV100494813; called by muse, mutect2, varscan2
- EGR1 | c.1534_1550del p.S512Cfs*24 | Frame Shift Del (DEL) | VAF 41/227 reads (18%) | called by mutect2, pindel, varscan2
- IGFL1 | c.266del p.K89Sfs*2 | Frame Shift Del (DEL) | VAF 42/245 reads (17%) | called by mutect2, pindel, varscan2
- IGKV2D-29 | c.17A>T p.Q6L | Missense Mutation (SNP) | VAF 45/212 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- KMT2D | c.9244_9248del p.R3082Gfs*14 | Frame Shift Del (DEL) | VAF 11/54 reads (20%) | called by mutect2, pindel, varscan2
- ZNF521 | c.3098del p.L1033Wfs*49 | Frame Shift Del (DEL) | VAF 9/51 reads (18%) | called by mutect2, pindel, varscan2
- ACKR3 | c.684C>T p.I228= | Silent (SNP) | VAF 11/118 reads (9%) | catalogued as rs143420114; called by muse, mutect2
- ADAT3 | c.1023A>G p.A341= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as COSV100280422; called by muse, mutect2
- AKAP12 | c.1998G>A p.P666= | Silent (SNP) | VAF 9/61 reads (15%) | catalogued as rs747947110, COSV53575956; called by muse, mutect2, varscan2
- BRINP2 | c.165G>T p.L55= | Silent (SNP) | VAF 24/137 reads (18%) | catalogued as COSV100838566; called by muse, varscan2
- CD2AP | c.1719G>A p.V573= | Silent (SNP) | VAF 22/132 reads (17%) | catalogued as rs1440066963, COSV100830701; called by muse, mutect2, varscan2
- CEP55 | c.930G>A p.E310= | Silent (SNP) | VAF 30/188 reads (16%) | catalogued as COSV101017200, COSV65184519; called by muse, mutect2, varscan2
- CNTNAP2 | c.2439T>C p.S813= | Silent (SNP) | VAF 51/248 reads (21%) | catalogued as COSV100674034; called by muse, mutect2, varscan2
- COL11A1 | c.1563G>A p.Q521= | Silent (SNP) | VAF 13/79 reads (16%) | catalogued as COSV100618406, COSV62200966; called by muse, mutect2, varscan2
- CPNE4 | c.291C>T p.D97= | Silent (SNP) | VAF 82/482 reads (17%) | catalogued as COSV101456853; called by muse, mutect2, varscan2
- CTH | c.1185G>A p.K395= | Silent (SNP) | VAF 14/142 reads (10%) | catalogued as COSV100697183; called by muse, mutect2, varscan2
- CTIF | c.1026G>T p.L342= | Silent (SNP) | VAF 131/588 reads (22%) | catalogued as COSV99838705; called by muse, mutect2, varscan2
- CUX2 | c.321G>A p.E107= | Silent (SNP) | VAF 39/203 reads (19%) | catalogued as rs770415393, COSV99921129; called by muse, mutect2, varscan2
- DCBLD2 | c.2061G>T p.G687= | Silent (SNP) | VAF 55/149 reads (37%) | catalogued as rs200647911, COSV99504554; called by muse, mutect2, varscan2
- FAH | c.498C>T p.V166= | Silent (SNP) | VAF 18/104 reads (17%) | catalogued as rs143712599; called by muse, mutect2, varscan2
- FAM131B | c.633C>A p.L211= | Silent (SNP) | VAF 18/99 reads (18%) | catalogued as COSV100578706; called by muse, mutect2, varscan2
- FBXO27 | c.489G>A p.K163= | Silent (SNP) | VAF 42/228 reads (18%) | catalogued as COSV53072418, COSV99494806; called by muse, mutect2, varscan2
- FRMPD4 | c.2520G>A p.L840= | Silent (SNP) | VAF 56/134 reads (42%) | catalogued as COSV101044413; called by muse, mutect2, varscan2
- HDAC1 | c.1011T>C p.F337= | Silent (SNP) | VAF 26/107 reads (24%) | catalogued as COSV100269726; called by muse, mutect2, varscan2
- IGFBP1 | c.712A>C p.R238= | Silent (SNP) | VAF 33/133 reads (25%) | catalogued as COSV99298899; called by muse, mutect2, varscan2
- ITGA8 | c.1101C>T p.S367= | Silent (SNP) | VAF 12/76 reads (16%) | catalogued as rs759346104, COSV100959935; called by muse, mutect2, varscan2
- KDM5B | c.3184C>T p.L1062= | Silent (SNP) | VAF 26/128 reads (20%) | catalogued as COSV99351666; called by muse, mutect2, varscan2
- KIF26A | c.336G>A p.G112= | Silent (SNP) | VAF 17/75 reads (23%) | catalogued as COSV100181732; called by muse, mutect2, varscan2
- KRT71 | c.1014G>A p.G338= | Silent (SNP) | VAF 18/101 reads (18%) | catalogued as COSV99922464; called by muse, mutect2, varscan2
- MAP2 | c.1281C>T p.T427= | Silent (SNP) | VAF 17/75 reads (23%) | catalogued as COSV99562012, COSV99562168; called by muse, mutect2, varscan2
- MFSD1 | c.840G>A p.V280= | Silent (SNP) | VAF 16/141 reads (11%) | catalogued as COSV99964186; called by muse, mutect2, varscan2
- MR1 | c.690A>T p.P230= | Silent (SNP) | VAF 17/96 reads (18%) | catalogued as COSV99295170; called by muse, mutect2, varscan2
- MYH13 | c.5745C>T p.D1915= | Silent (SNP) | VAF 15/310 reads (5%) | catalogued as rs1264834193, COSV99356003; called by muse, mutect2
- NDST1 | c.1641G>T p.V547= | Silent (SNP) | VAF 12/56 reads (21%) | catalogued as COSV99938562, COSV99939150; called by muse, mutect2, varscan2
- OLIG3 | c.321C>T p.R107= | Silent (SNP) | VAF 13/110 reads (12%) | catalogued as rs1487922443, COSV62988597; called by muse, mutect2, varscan2
- OR2L3 | c.315A>T p.A105= | Silent (SNP) | VAF 65/344 reads (19%) | catalogued as COSV100742091; called by muse, mutect2, varscan2
- OR4M1 | c.24G>A p.K8= | Silent (SNP) | VAF 42/320 reads (13%) | catalogued as COSV100271607; called by muse, mutect2, varscan2
- PRDM16 | c.2088C>T p.I696= | Silent (SNP) | VAF 24/149 reads (16%) | catalogued as rs755442577, COSV99579629; called by muse, mutect2, varscan2
- PTGER3 | c.723G>T p.A241= | Silent (SNP) | VAF 28/124 reads (23%) | catalogued as rs1245147274, COSV100139918; called by muse, mutect2, varscan2
- RGS22 | c.987G>A p.Q329= | Silent (SNP) | VAF 34/98 reads (35%) | catalogued as COSV100693999; called by muse, mutect2, varscan2
- SDCCAG8 | c.1980G>A p.K660= | Silent (SNP) | VAF 35/139 reads (25%) | catalogued as rs1404435698, COSV100654787; called by muse, mutect2, varscan2
- SELP | c.99A>G p.L33= | Silent (SNP) | VAF 21/132 reads (16%) | catalogued as COSV99741417; called by muse, mutect2, varscan2
- SIDT1 | c.1377G>C p.V459= | Silent (SNP) | VAF 64/186 reads (34%) | catalogued as COSV99332960, COSV99334982; called by muse, mutect2, varscan2
- SLC10A6 | c.687C>T p.I229= | Silent (SNP) | VAF 10/65 reads (15%) | catalogued as COSV99907442; called by muse, mutect2, varscan2
- SLC4A1AP | c.231A>G p.P77= | Silent (SNP) | VAF 19/119 reads (16%) | catalogued as COSV100389736; called by muse, mutect2, varscan2
- TBX18 | c.1134T>C p.T378= | Silent (SNP) | VAF 13/135 reads (10%) | catalogued as COSV100858617; called by muse, mutect2, varscan2
- TMEM132D | c.477C>G p.R159= | Silent (SNP) | VAF 6/66 reads (9%) | catalogued as COSV101399956; called by muse, mutect2
- TRIM75P | c.978T>C p.P326= | Silent (SNP) | VAF 11/92 reads (12%) | called by muse, mutect2, varscan2
- TUBA3D | c.1200C>A p.A400= | Silent (SNP) | VAF 66/420 reads (16%) | catalogued as COSV100343036; called by muse, varscan2
- WFS1 | c.1881G>T p.L627= | Silent (SNP) | VAF 87/363 reads (24%) | catalogued as COSV99901719; called by muse, mutect2, varscan2
- ZFHX4 | c.10488C>T p.S3496= | Silent (SNP) | VAF 16/140 reads (11%) | catalogued as COSV99269399; called by muse, mutect2, varscan2
- ZNF135 | c.9T>C p.P3= | Silent (SNP) | VAF 19/163 reads (12%) | catalogued as COSV100537011; called by muse, mutect2
- ZNF438 | c.1185A>C p.A395= | Silent (SNP) | VAF 28/145 reads (19%) | catalogued as COSV100063030; called by muse, mutect2, varscan2
- BMP1 | c.731-153C>T | Intron (SNP) | VAF 22/84 reads (26%) | catalogued as COSV100110282; called by muse, mutect2, varscan2
- DNAH8 | chr6:38723120 C>T | 5'Flank (SNP) | VAF 29/104 reads (28%) | catalogued as rs954540376, COSV100545902, COSV100547542; called by muse, mutect2, varscan2
- EI24P4 | n.915C>A | RNA (SNP) | VAF 107/387 reads (28%) | called by muse, mutect2, varscan2
- NEDD4L | c.122+29795G>A | Intron (SNP) | VAF 3/42 reads (7%) | catalogued as COSV99897116; called by muse, mutect2
- OR2U1P | n.616_617del | RNA (DEL) | VAF 8/55 reads (15%) | called by mutect2, pindel, varscan2
- PSEN2 | c.-20-1175G>T | Intron (SNP) | VAF 96/407 reads (24%) | catalogued as rs768163661, COSV100423390; called by muse, mutect2, varscan2
- VAPA | c.418-5409T>A | Intron (SNP) | VAF 67/160 reads (42%) | catalogued as COSV100486204; called by muse, mutect2, varscan2
